Somatic mutation profile of tumor specimen ALCH-B1Y5-TTP1-A (aliquot ALCH-B1Y5-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B1Y5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.9 years (20,402 days).
Specimen ALCH-B1Y5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e44f042-a720-4655-847a-1cf34aad7309.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1Y5-NB1-A (Blood Derived Normal), aliquot ALCH-B1Y5-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24df8bfb-a081-479e-b47b-9157215c1cd0

The open-access MAF lists 166 somatic variants for this specimen: 116 protein-altering or splice-affecting, 36 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 36, Nonsense Mutation 7, Splice Site 4, Intron 4, RNA 4, Frame Shift Del 3, 3'UTR 2, 5'UTR 2, Translation Start Site 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 58/418 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58682804, COSV58699096, COSV58719034; called by muse, mutect2, varscan2
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 45/229 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADH1B | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 63/347 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs1239470105; called by muse, mutect2, varscan2
- AKAP4 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV62074391; called by muse, mutect2, varscan2
- C1QL4 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.281); catalogued as COSV99227012; called by muse, mutect2, varscan2
- CDHR4 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1212737616; called by muse, mutect2, varscan2
- COL22A1 | c.2004A>T p.Q668H | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as rs918215175; called by muse, mutect2, varscan2
- FBN1 | c.4487C>T p.T1496M | Missense Mutation (SNP) | VAF 102/509 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs776199613; called by muse, mutect2, varscan2
- HHLA1 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 63/476 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as rs1268983359; called by muse, mutect2, varscan2
- ILDR1 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 84/429 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs727503098, COSV56547645; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IPO5 | c.2436A>C p.Q812H | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as rs1445219439; called by muse, varscan2
- IRX2 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.109); catalogued as rs773495657; called by muse, mutect2, varscan2
- ITGA4 | c.1601A>G p.Y534C | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751609596; called by muse, varscan2
- KCNK1 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 76/327 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as rs778403770; called by muse, mutect2, varscan2
- KIF21B | c.1323G>T p.M441I | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs1431469227; called by muse, mutect2, varscan2
- LRRC3B | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.705); catalogued as COSV101186020; called by muse, mutect2, varscan2
- LZTR1 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as rs780578255; called by muse, mutect2, varscan2
- MAGI2 | c.2209C>A p.P737T | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV100836848; called by muse, mutect2, varscan2
- MMP8 | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs1354587190; called by muse, mutect2, varscan2
- MYO10 | c.5254G>T p.D1752Y | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs188023536, COSV57023562, COSV99945614; called by muse, mutect2, varscan2
- NEDD4L | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); catalogued as COSV99894396; called by muse, mutect2, varscan2
- NYAP2 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1309957389, COSV55998211; called by muse, mutect2, varscan2
- OR3A2 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 97/434 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.417); catalogued as COSV101375065; called by muse, mutect2, varscan2
- OR5H1 | c.150G>T p.W50C | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV63403118; called by muse, mutect2, varscan2
- OR6S1 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.05); catalogued as COSV57837557; called by muse, mutect2, varscan2
- PGK2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs200356678; called by muse, mutect2, varscan2
- POU4F2 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs575863247; called by muse, mutect2, varscan2
- RB1 | c.955A>T p.K319* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as COSV99924370; called by muse, mutect2, varscan2
- SETBP1 | c.3715G>A p.A1239T | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs767991773; called by muse, mutect2, varscan2
- SLC25A52 | c.166G>A p.A56T (on ENST00000672005; = p.A46T on NM_001034172.4) | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs139162190; called by muse, mutect2, varscan2
- SLMAP | c.1525C>A p.H509N (on ENST00000428312 / NM_001377924.1; = p.H571N on NM_007159.5) | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.06); catalogued as COSV99909227; called by muse, mutect2
- SPATA31A6 | c.3290G>A p.R1097K | Missense Mutation (SNP) | VAF 68/425 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs766852910, COSV60534042; called by muse, mutect2, varscan2
- SPATS1 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.895); catalogued as COSV55823387, COSV99913356; called by muse, varscan2
- TMPRSS11E | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV59520393; called by muse, mutect2, varscan2
- UNC13C | c.3006+1G>T p.X1002_splice | Splice Site (SNP) | VAF 17/116 reads (15%) | catalogued as COSV52892204; called by muse, mutect2, varscan2
- UNC13C | c.5434T>A p.F1812I | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV52915044; called by muse, mutect2, varscan2
- VCAN | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54115692; called by muse, mutect2, varscan2
- WNT9A | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs552502207, COSV55293545; called by muse, mutect2, varscan2
- ZEB1 | c.2300C>A p.P767H | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58050966; called by muse, mutect2, varscan2
- ACTRT3 | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAD1 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ANAPC2 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- APOB | c.10540G>T p.A3514S | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- B3GLCT | c.271-1G>A p.X91_splice | Splice Site (SNP) | VAF 63/363 reads (17%) | called by muse, mutect2, varscan2
- BLZF1 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC142 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CIC | c.126del p.F43Sfs*162 | Frame Shift Del (DEL) | VAF 40/222 reads (18%) | called by mutect2, pindel, varscan2
- CLEC7A | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CSRNP1 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- DCDC1 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX54 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, varscan2
- DLEU7 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DNAJA3 | c.767G>A p.C256Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOCK2 | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSC2 | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- EML6 | c.3881A>T p.Y1294F | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- EPYC | c.419C>G p.P140R | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ERN2 | c.663G>A p.W221* | Nonsense Mutation (SNP) | VAF 54/314 reads (17%) | called by muse, varscan2
- EYS | c.5978C>A p.T1993K | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- FAM221A | c.173G>A p.W58* | Nonsense Mutation (SNP) | VAF 46/336 reads (14%) | called by muse, varscan2
- FAT1 | c.1061A>G p.H354R | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBXO21 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FCGBP | c.12605G>T p.C4202F | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FER1L5 | c.598C>A p.R200S | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR141 | c.723C>A p.Y241* | Nonsense Mutation (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- GPR75 | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); called by mutect2, varscan2
- GRAMD1C | c.698A>T p.D233V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.399); called by muse, varscan2
- GRB10 | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- GRIA2 | c.2297C>G p.A766G | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); called by muse, varscan2
- GRIA4 | c.1786T>C p.F596L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.173); called by muse, varscan2
- GRID2IP | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- GRIN3A | c.1234C>A p.L412I | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GRIN3A | c.979A>T p.M327L | Missense Mutation (SNP) | VAF 139/339 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDC | c.1313C>G p.A438G | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- HNF4A | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HYDIN | c.1227+1G>T p.X409_splice | Splice Site (SNP) | VAF 6/53 reads (11%) | called by mutect2, varscan2
- IFNA4 | c.400del p.L134* | Frame Shift Del (DEL) | VAF 43/413 reads (10%) | called by pindel, varscan2
- IFTAP | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- IL4R | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ITGAM | c.1661A>T p.Y554F (on ENST00000648685 / NM_001145808.2; = p.Y553F on NM_000632.4) | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- KCNT2 | c.2165T>G p.I722R | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- KHNYN | c.1576A>C p.R526= | Splice Region (SNP) | VAF 73/284 reads (26%) | called by muse, mutect2, varscan2
- LMX1A | c.1123del p.M375Cfs*16 | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | called by mutect2, pindel*, varscan2
- LTBP1 | c.4091C>T p.A1364V (on ENST00000404816 / NM_206943.4; = p.A1038V on NM_000627.4) | Missense Mutation (SNP) | VAF 47/360 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- MARCHF11 | c.1112A>T p.Y371F | Missense Mutation (SNP) | VAF 99/376 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MBL2 | c.74G>A p.C25Y | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, varscan2
- MDC1 | c.4252A>T p.T1418S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- MFN1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGAM | c.1477C>A p.P493T | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MUC5AC | c.13667C>A p.A4556D | Missense Mutation (SNP) | VAF 86/524 reads (16%) | SIFT deleterious (0.04); called by muse, varscan2
- NAP1L2 | c.612G>T p.E204D | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.812); called by muse, varscan2
- NFATC1 | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- OLFML2B | c.663C>A p.S221R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR51M1 | c.72C>A p.F24L | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR5H1 | c.149G>T p.W50L | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- PAPPA | c.1819C>A p.P607T | Missense Mutation (SNP) | VAF 122/341 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PHF14 | c.2747A>G p.Q916R | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PLAA | c.1060C>A p.R354S | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); called by muse, varscan2
- PLEKHM1 | c.2969A>G p.H990R | Missense Mutation (SNP) | VAF 118/466 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PRR23C | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PUF60 | c.733G>T p.V245L (on ENST00000526683 / NM_001362896.2; = p.V228L on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- RAD21L1 | c.461A>C p.Q154P | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAG2 | c.1187A>T p.D396V | Missense Mutation (SNP) | VAF 64/369 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RHAG | c.1112C>A p.T371K | Missense Mutation (SNP) | VAF 92/475 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- SMURF1 | c.1819C>G p.L607V | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TGM1 | c.631A>T p.T211S | Missense Mutation (SNP) | VAF 144/504 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, varscan2
- TNFAIP3 | c.192C>G p.I64M | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- TRIB1 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 135/361 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM3 | c.2158G>T p.A720S | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- TRIM42 | c.1811C>G p.P604R | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTC29 | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TTC7A | c.1251G>A p.W417* | Nonsense Mutation (SNP) | VAF 52/350 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.670-2A>G p.X224_splice | Splice Site (SNP) | VAF 88/441 reads (20%) | called by muse, mutect2, varscan2
- UACA | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP57 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- ZNF107 | c.1838G>T p.C613F | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCD1 | c.1734C>T p.A578= | Silent (SNP) | VAF 82/218 reads (38%) | called by muse, mutect2, varscan2
- ADCY1 | c.726G>T p.A242= | Silent (SNP) | VAF 57/369 reads (15%) | called by muse, varscan2
- CDH7 | c.87C>A p.L29= | Silent (SNP) | VAF 46/276 reads (17%) | called by muse, varscan2
- CDK15 | c.642C>T p.Y214= (on ENST00000652192 / NM_001366386.2; = p.Y163= on NM_139158.2) | Silent (SNP) | VAF 25/177 reads (14%) | called by muse, mutect2, varscan2
- CEP128 | c.2511A>T p.A837= | Silent (SNP) | VAF 35/110 reads (32%) | called by muse, mutect2, varscan2
- EVX2 | c.474G>T p.S158= | Silent (SNP) | VAF 26/151 reads (17%) | called by muse, mutect2, varscan2
- FAT2 | c.918T>C p.Y306= | Silent (SNP) | VAF 13/173 reads (8%) | catalogued as rs764466677; called by muse, mutect2
- FHOD3 | c.1134C>A p.T378= | Silent (SNP) | VAF 25/195 reads (13%) | called by muse, mutect2, varscan2
- GRM3 | c.432G>T p.G144= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as COSV64475378; called by muse, varscan2
- HPCAL4 | c.258C>A p.I86= | Silent (SNP) | VAF 81/351 reads (23%) | called by muse, mutect2, varscan2
- ITGB8 | c.1098A>T p.I366= | Silent (SNP) | VAF 34/293 reads (12%) | called by muse, mutect2, varscan2
- LRRN3 | c.1035T>A p.A345= | Silent (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- MAD1L1 | c.2055C>T p.T685= | Silent (SNP) | VAF 39/232 reads (17%) | catalogued as rs377713158; called by muse, mutect2, varscan2
- MUC16 | c.18864C>T p.A6288= | Silent (SNP) | VAF 38/127 reads (30%) | called by muse, mutect2, varscan2
- NDUFS3 | c.147A>G p.P49= | Silent (SNP) | VAF 110/592 reads (19%) | called by muse, mutect2, varscan2
- NKX6-2 | c.196C>A p.R66= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- OR14K1 | c.105G>T p.T35= | Silent (SNP) | VAF 61/222 reads (27%) | catalogued as rs560139926; called by muse, mutect2, varscan2
- P2RX3 | c.15C>T p.S5= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs748037477, COSV53478229; called by muse, mutect2, varscan2
- PALLD | c.135G>T p.L45= | Silent (SNP) | VAF 55/199 reads (28%) | called by muse, mutect2, varscan2
- PCDH15 | c.1482C>A p.I494= | Silent (SNP) | VAF 44/238 reads (18%) | catalogued as COSV57300088; called by muse, mutect2, varscan2
- PDLIM5 | c.582G>C p.L194= | Silent (SNP) | VAF 34/244 reads (14%) | called by muse, mutect2, varscan2
- PER1 | c.1938C>T p.T646= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs1386681948; called by muse, mutect2, varscan2
- PFAS | c.3939A>G p.P1313= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as rs1366336503; called by muse, mutect2, varscan2
- PRSS53 | c.36G>A p.A12= | Silent (SNP) | VAF 33/244 reads (14%) | catalogued as rs768988096; called by muse, mutect2, varscan2
- PXDN | c.1428C>T p.D476= | Silent (SNP) | VAF 23/134 reads (17%) | called by muse, varscan2
- RBSN | c.2127C>T p.N709= | Silent (SNP) | VAF 27/126 reads (21%) | called by muse, mutect2, varscan2
- RXRA | c.228C>T p.S76= | Silent (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.459A>G p.P153= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2
- SMCR8 | c.2310C>T p.S770= | Silent (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- SOX30 | c.309C>T p.F103= | Silent (SNP) | VAF 27/264 reads (10%) | catalogued as rs772377894; called by muse, mutect2, varscan2
- SP8 | c.1224G>T p.R408= (on ENST00000361443 / NM_198956.4; = p.R426= on NM_182700.6) | Silent (SNP) | VAF 75/492 reads (15%) | called by muse, mutect2, varscan2
- UPP1 | c.390G>T p.R130= | Silent (SNP) | VAF 93/373 reads (25%) | called by muse, mutect2, varscan2
- VCAN | c.5727A>G p.S1909= | Silent (SNP) | VAF 76/542 reads (14%) | catalogued as COSV54110556; called by muse, mutect2, varscan2
- XKR7 | c.483T>C p.P161= | Silent (SNP) | VAF 31/190 reads (16%) | catalogued as rs1224710395; called by muse, mutect2, varscan2
- ZNF284 | c.1401C>A p.A467= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV101398971; called by muse, mutect2, varscan2
- ZNF697 | c.1392C>T p.P464= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as rs1335734817; called by muse, mutect2, varscan2
- C5orf64 | n.512+51967G>T | Intron (SNP) | VAF 38/368 reads (10%) | catalogued as rs1171356755; called by muse, mutect2, varscan2
- CLK2P1 | n.947G>A | RNA (SNP) | VAF 108/531 reads (20%) | catalogued as rs757485518; called by muse, mutect2, varscan2
- DPRX | c.-24C>A | 5'UTR (SNP) | VAF 35/141 reads (25%) | catalogued as COSV64949839; called by muse, mutect2, varscan2
- FAM71E2 | c.-25C>A | 5'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- LDHA | chr11:18407947 C>T | 3'Flank (SNP) | VAF 45/348 reads (13%) | catalogued as rs923756666; called by muse, mutect2
- MIR1265 | n.40C>A | RNA (SNP) | VAF 32/249 reads (13%) | called by muse, mutect2, varscan2
- MMGT1 | chrX:135974658 C>T | 5'Flank (SNP) | VAF 45/123 reads (37%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92996G>C | Intron (SNP) | VAF 25/124 reads (20%) | called by muse, mutect2, varscan2
- PCDH11X | n.542G>T | RNA (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- PLA2G4C | c.*18G>T | 3'UTR (SNP) | VAF 36/176 reads (20%) | catalogued as COSV53154800; called by muse, mutect2, varscan2
- PPP2R2B | c.1052+847A>C | Intron (SNP) | VAF 35/292 reads (12%) | called by muse, mutect2, varscan2
- SLC25A3 | c.*24del | 3'UTR (DEL) | VAF 35/253 reads (14%) | called by mutect2, pindel*, varscan2*
- SNORD115-1 | n.34G>A | RNA (SNP) | VAF 60/403 reads (15%) | catalogued as rs763832272; called by muse, mutect2, varscan2
- WARS1 | c.1113+63G>A | Intron (SNP) | VAF 14/255 reads (5%) | catalogued as rs1204588034; called by muse, mutect2
